Somatic mutation profile of tumor specimen 0DMBMD from CCDI case PBCAJH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 8.3 years (3,026 days).
Specimen 0DMBMD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8779a3f-95e8-4cfa-bb37-d06d01cf48ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBLL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c532312-d1ed-4f70-926b-e15078a118a4

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Del 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JPH1 | c.1195C>A p.R399S | Missense Mutation (SNP) | VAF 366/740 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.235); catalogued as rs766327331; called by muse, mutect2, varscan2
- STX19 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 387/889 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs768929991; called by muse, mutect2, varscan2
- DNAH14 | c.1960del p.L654Ffs*11 (on ENST00000445597; = p.L683Ffs*11 on NM_001367479.1) | Frame Shift Del (DEL) | VAF 223/319 reads (70%) | called by mutect2, pindel, varscan2
- GABRG2 | c.1115T>G p.V372G (on ENST00000361925 / NM_001375343.1; = p.V332G on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 398/924 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBFOX1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 90/860 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WFDC2 | c.45C>A p.L15= | Silent (SNP) | VAF 313/1005 reads (31%) | catalogued as rs768351013; called by muse, mutect2, varscan2
- SPG7 | c.376+4227C>A | Intron (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
